Somatic mutation profile of tumor specimen 0DPZTN from CCDI case PBCEKF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 19.6 years (7,169 days).
Specimen 0DPZTN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a3ecf17-ab04-4d27-86cf-8f9146072979.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPZUG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e36db760-61cf-4ed1-9a8d-749624a7bd47

The open-access MAF lists 22 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Intron 3, 3'UTR 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 152/409 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 228/361 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- NLRP4 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 104/323 reads (32%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.534); catalogued as rs768142392, COSV56712077; called by muse, varscan2
- SLC13A5 | c.232-8C>T | Splice Region (SNP) | VAF 20/126 reads (16%) | catalogued as rs566063560; called by muse, varscan2
- SPEG | c.8158G>A p.V2720M | Missense Mutation (SNP) | VAF 184/523 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as rs1559431395; called by muse, varscan2
- DDR2 | c.713G>A p.G238D | Missense Mutation (SNP) | VAF 158/528 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- KLHL35 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 69/198 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, varscan2
- KRT28 | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 219/699 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, varscan2
- PHF19 | c.42+1G>A p.X14_splice | Splice Site (SNP) | VAF 142/472 reads (30%) | called by muse, varscan2
- PLD6 | c.286C>G p.L96V | Missense Mutation (SNP) | VAF 70/190 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.193); called by muse, varscan2
- POGZ | c.3819G>T p.K1273N | Missense Mutation (SNP) | VAF 273/719 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, varscan2
- ZP1 | c.756A>T p.K252N | Missense Mutation (SNP) | VAF 168/605 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.171); called by muse, varscan2
- DNAH5 | c.12603C>T p.F4201= | Silent (SNP) | VAF 182/621 reads (29%) | catalogued as rs758897089, COSV54223789; called by muse, varscan2
- DYNC1H1 | c.5970C>T p.Y1990= | Silent (SNP) | VAF 160/380 reads (42%) | catalogued as rs751526144, COSV64138583; ClinVar: likely benign / benign; called by muse, varscan2
- HMGN5 | c.834A>G p.P278= | Silent (SNP) | VAF 148/460 reads (32%) | called by muse, varscan2
- PRSS41 | c.867C>T p.C289= | Silent (SNP) | VAF 85/221 reads (38%) | catalogued as rs767785558, COSV68786843; called by muse, varscan2
- SLC35A1 | c.645A>G p.L215= | Silent (SNP) | VAF 330/1002 reads (33%) | catalogued as rs1354272700; called by muse, varscan2
- C1QTNF3 | c.84+59G>A | Intron (SNP) | VAF 120/466 reads (26%) | called by muse, varscan2
- ERFE | c.*25C>T | 3'UTR (SNP) | VAF 102/236 reads (43%) | called by muse, varscan2
- HECW2 | c.*42G>A | 3'UTR (SNP) | VAF 206/565 reads (36%) | catalogued as COSV99646637; called by muse, varscan2
- PLEKHG3 | c.351+1033T>C | Intron (SNP) | VAF 238/544 reads (44%) | catalogued as rs1480647285; called by muse, varscan2
- SEC31B | c.3025-98C>G | Intron (SNP) | VAF 48/146 reads (33%) | called by muse, varscan2
